Somatic mutation profile of tumor specimen TARGET-20-PARWXU-04A (aliquot TARGET-20-PARWXU-04A-01D) from TARGET case TARGET-20-PARWXU, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.5 years (557 days).
Specimen TARGET-20-PARWXU-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d226e4af-e978-4d50-9a0e-45b26415eecb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARWXU-14A (Bone Marrow Normal), aliquot TARGET-20-PARWXU-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b0e222c-3d8e-4384-84d4-458c2ad977e8

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 13, Silent 7, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 172/446 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADCY2 | c.1578G>A p.T526= | Splice Region (SNP) | VAF 67/147 reads (46%) | catalogued as COSV57901389; called by muse, mutect2, varscan2
- ASTN2 | c.1991G>A p.R664H (on ENST00000313400 / NM_001365069.1; = p.R613H on NM_014010.5) | Missense Mutation (SNP) | VAF 94/222 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs750439078, COSV57813374; called by muse, mutect2, varscan2
- CALML5 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs990816257, COSV100981221; called by muse, mutect2, varscan2
- CDC73 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 271/717 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM072926, COSV66465222; called by muse, varscan2
- GLB1L2 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 152/340 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs202239114, COSV60278512; called by muse, mutect2, varscan2
- KDM6A | c.3334_3338dup p.A1115Yfs*7 | Frame Shift Ins (INS) | VAF 196/258 reads (76%) | catalogued as rs753442927; called by mutect2, varscan2
- MYH2 | c.5002C>T p.R1668W | Missense Mutation (SNP) | VAF 85/241 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs569489518, COSV55431886, COSV55435762; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PMEPA1 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); catalogued as rs924182556, COSV55696564; called by muse, mutect2, varscan2
- PWWP2A | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 127/263 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100194144, COSV61048190; called by muse, mutect2, varscan2
- TET2 | c.2903C>T p.P968L | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV54433469; called by muse, mutect2, varscan2
- TRPV1 | c.2218C>T p.R740W | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408850756; called by muse, mutect2, varscan2
- UTY | c.3173G>C p.R1058P | Missense Mutation (SNP) | VAF 123/146 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as rs767515011; called by muse, mutect2, varscan2
- SLCO5A1 | c.733A>T p.T245S | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF675 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 121/250 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- ADAMTS7 | c.3219C>T p.H1073= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs202058579; called by muse, mutect2, varscan2
- FAT1 | c.12006G>A p.S4002= | Silent (SNP) | VAF 67/186 reads (36%) | catalogued as rs780198819, COSV71676078; called by muse, mutect2, varscan2
- HTRA1 | c.1347C>T p.S449= | Silent (SNP) | VAF 117/283 reads (41%) | catalogued as rs761964682, COSV64564113; called by muse, mutect2, varscan2
- MTA3 | c.405C>T p.V135= | Silent (SNP) | VAF 181/480 reads (38%) | catalogued as COSV101290761, COSV68136439, COSV68136760; called by muse, mutect2, varscan2
- PATJ | c.237G>A p.R79= | Silent (SNP) | VAF 264/671 reads (39%) | called by muse, varscan2
- UBAP2L | c.2946G>A p.S982= | Silent (SNP) | VAF 107/244 reads (44%) | catalogued as rs377262072; called by muse, mutect2, varscan2
- ZNF536 | c.159G>T p.R53= | Silent (SNP) | VAF 29/69 reads (42%) | catalogued as COSV62828288; called by muse, mutect2, varscan2
